CCDI case PBCPXM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/c676b716-a18c-4cd7-91a5-c897931faef1

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 5.1 years (1,861 days).

Biospecimens (2 samples)
- Sample 0DX7ET: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DX7FR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
